TCGA case TCGA-E1-5305 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a0bc5147-d9b4-41fd-8df3-a241d23722e8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 34 years; Vital status: Dead; Days to death: 2,433 days (6.7 years).

Diagnoses (2)
1. Astrocytoma, anaplastic (the primary disease): ICD-O-3 morphology code: 9401/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 34.6 years (12,655 days); Year of diagnosis: 2000; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Seizures; Sites of involvement: Brain, Frontal lobe.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 88 days; Course number: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 148 days; Days to treatment end: 593 days (1.6 years); Number of cycles: 12; Treatment dose: 25,200 mg; Prescribed dose: 50; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 148 days; Days to treatment end: 593 days (1.6 years); Number of cycles: 12; Treatment dose: 18,600 mg; Prescribed dose: 150; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Hydroxyurea; Initial disease status: Progressive Disease; Days to treatment start: 1,636 days (4.5 years); Days to treatment end: 1,825 days (5.0 years); Number of cycles: 6; Treatment dose: 84,000 mg; Prescribed dose: 500; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Imatinib Mesylate; Initial disease status: Progressive Disease; Days to treatment start: 1,636 days (4.5 years); Days to treatment end: 1,825 days (5.0 years); Number of cycles: 6; Treatment dose: 84,000 mg; Prescribed dose: 500; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 1,861 days (5.1 years); Days to treatment end: 1,994 days (5.5 years); Number of cycles: 6; Treatment dose: 12,000 mg; Prescribed dose: 200; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 1,861 days (5.1 years); Days to treatment end: 1,994 days (5.5 years); Number of cycles: 6; Treatment dose: 14,400 mg; Prescribed dose: 200; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,994 days (5.5 years); Days to treatment end: 2,093 days (5.7 years); Number of cycles: 2; Treatment dose: 5,440 mg; Prescribed dose: 340; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 2,128 days (5.8 years); Days to treatment end: 2,241 days (6.1 years); Number of cycles: 4; Treatment dose: 10,192 mg; Prescribed dose: 10; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Progressive Disease; Days to treatment start: 2,128 days (5.8 years); Days to treatment end: 2,241 days (6.1 years); Number of cycles: 4; Treatment dose: 81,760 mg; Prescribed dose: 730; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Days to treatment start: 2,280 days (6.2 years); Days to treatment end: 2,331 days (6.4 years); Number of cycles: 1; Treatment dose: 220 mg; Prescribed dose: 110; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Treatment given: Treatment type: Steroid Therapy; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.
2. Recurrence of diagnosis 1 (Astrocytoma, anaplastic). Age at diagnosis: 39.0 years (14,259 days); Days to diagnosis: 1,604 days (4.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 1,623 days (4.4 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Distant Site.

Follow-up (4 entries)
- Day 89 (post adjuvant therapy): Karnofsky performance status: 100.
- Day 1,604 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,604 days (4.4 years).
- Day 1,631 (post adjuvant therapy): Karnofsky performance status: 90.
- Days to follow up: 2,433 days (6.7 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Allergies / Asthma; Risk factors: Asthma / Allergy, Mold or Dust.
- Timepoint category: Prior to Diagnosis; Risk factors: Seizure.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-E1-5305-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-E1-5305-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-E1-5305-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-E1-5305-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Astrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy; Tumor site: Supratentorial, Frontal Lobe; Supratentorial localization: Not listed in Medical Record; History seizures: Yes; History headaches: No; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: 0 - 30 Days; History asthma: Yes; History eczema: No; Histor hay fever: No; History dust mold allergy: Yes; History neoadjuvant steroid treatment: Yes; History neoadjuvant medication: Yes; Family history brain tumor: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 2; Pharmaceutical therapy drug name: VP-16; Therapy regimen: Progression.
- Drug treatment 3: Regimen number: 4; Therapy regimen: Progression.
- Drug treatment 5: Regimen number: 3; Pharmaceutical therapy drug name: Hydroyurea; Therapy regimen: Progression.
- Drug treatment 7: Regimen number: 3; Pharmaceutical therapy drug name: Gleevec; Therapy regimen: Progression.
- Drug treatment 8: Regimen number: 5; Pharmaceutical therapy drug name: CPT-11; Therapy regimen: Progression.
- Drug treatment 8, Route of administrations: Route of administration: IV.
- Drug treatment 9: Regimen number: 6; Pharmaceutical therapy drug name: Cytoxan; Therapy regimen: Progression.
- Drug treatment 10: Regimen number: 6; Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Stable Disease; New tumor event surgery: Yes; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: No; Performance status timing: Post-Adjuvant Therapy; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,433 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,433 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,604 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-E1-5305-01A-01D-1892-01): tumor purity 0.77, ploidy 1.95, whole-genome doublings 0.
